Somatic mutation profile of tumor specimen MMRF_1049_2_BM_CD138pos (aliquot MMRF_1049_2_BM_CD138pos_T2_KHS5U_K14041) from MMRF case MMRF_1049, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.0 years (24,843 days).
Specimen MMRF_1049_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5aa8029-7d91-4363-b8db-28060d8ffcdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1049_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1049_1_PB_Whole_C2_KHS5U_K14065; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d730f5c-7082-4100-a975-7a38af530577

The open-access MAF lists 146 somatic variants for this specimen: 58 protein-altering or splice-affecting, 15 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 28, Intron 24, Silent 15, 5'UTR 11, RNA 6, Nonsense Mutation 4, 5'Flank 3, Translation Start Site 1, Frame Shift Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS18 | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 53/74 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.642); catalogued as rs1355815263, COSV51402328; called by muse, mutect2, varscan2
- BMP4 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs1258588645; called by muse, mutect2, varscan2
- CDK2AP1 | c.149C>T p.T50I | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as rs762855598; called by muse, mutect2, varscan2
- EGR1 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs199695186; called by muse, varscan2
- ELAVL4 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 80/217 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs200396874, COSV100836643; called by muse, mutect2, varscan2
- GABRA5 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 164/302 reads (54%) | catalogued as COSV59475659; called by muse, mutect2, varscan2
- GJD2 | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 62/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV51747204; called by muse, mutect2, varscan2
- HKDC1 | c.586C>A p.H196N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100664333; called by muse, mutect2, varscan2
- IGHV2-70 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs775504623; called by muse, varscan2
- IGHV2-70 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs377422798; called by muse, varscan2
- IGHV4-34 | c.326G>C p.S109T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs765275600; called by muse, mutect2, varscan2
- IGKV4-1 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 112/137 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as rs368410084; called by muse, mutect2, varscan2
- IGSF9 | c.2296G>A p.A766T (on ENST00000368094 / NM_001135050.2; = p.A750T on NM_020789.4) | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.177); catalogued as rs906876689; called by muse, mutect2, varscan2
- IRS4 | c.3226C>T p.Q1076* | Nonsense Mutation (SNP) | VAF 48/82 reads (59%) | catalogued as COSV100929429; called by muse, mutect2, varscan2
- KCNK3 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1439928866; called by muse, mutect2, varscan2
- KCTD17 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as rs1261369510; called by muse, mutect2, varscan2
- KLRF1 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54380568; called by muse, mutect2, varscan2
- MISP | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV53119921; called by muse, mutect2, varscan2
- NRP2 | c.2323G>A p.V775M | Missense Mutation (SNP) | VAF 29/257 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.185); catalogued as rs149128054; called by muse, mutect2, varscan2
- OR4D5 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 71/132 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs141977995, COSV100189634; called by muse, mutect2, varscan2
- PCDHGA3 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53951173; called by muse, mutect2, varscan2
- PHACTR3 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.347); catalogued as rs868038336; called by muse, mutect2
- PLAT | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753993747; called by muse, mutect2, varscan2
- SALL3 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs750854739; called by muse, mutect2, varscan2
- SYNGAP1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs574603811; called by muse, mutect2, varscan2
- TSPOAP1 | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.239); catalogued as rs765140985, COSV52109382; called by muse, mutect2, varscan2
- TTN | c.2227G>A p.A743T (on ENST00000591111; = p.A697T on NM_003319.4) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | PolyPhen benign (0.001); catalogued as rs370728359; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ZFP57 | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs564988086; called by muse, mutect2, varscan2
- ZNF223 | c.233C>A p.S78* | Nonsense Mutation (SNP) | VAF 61/360 reads (17%) | catalogued as COSV71571828; called by muse, mutect2, varscan2
- AFTPH | c.55G>T p.G19* | Nonsense Mutation (SNP) | VAF 100/485 reads (21%) | called by muse, mutect2, varscan2
- AP4B1 | c.850G>T p.A284S | Missense Mutation (SNP) | VAF 69/229 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ASPM | c.2657C>T p.T886I | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- B3GALNT1 | c.475del p.T159Pfs*8 | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- CCNC | c.448T>G p.L150V | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- CNGA2 | c.1514A>G p.D505G | Missense Mutation (SNP) | VAF 108/139 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWH43 | c.449A>T p.Q150L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HDHD2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- HSPD1 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGBP1P2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- IGHV2-70 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.352); called by mutect2, varscan2
- IGHV2-70D | c.263T>C p.L88P | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- IRAG1 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); called by muse, varscan2
- MNT | c.223G>C p.A75P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T29 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 133/514 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PCDH15 | c.4289C>A p.A1430E | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.199); called by muse, varscan2
- PRDM9 | c.382T>C p.S128P | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PRMT8 | c.557G>C p.W186S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN22 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- RAB3A | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- RASGRF2 | c.2165G>A p.C722Y | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- RPL10 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0.05); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SLC18A3 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- SP9 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.119); called by muse, mutect2
- SUPT5H | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TENT5C | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGM1 | c.509-2A>T p.X170_splice | Splice Site (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- TMEM26 | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRBV6-8 | c.112A>C p.M38L | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ABCA1 | c.6765A>G p.K2255= | Silent (SNP) | VAF 102/368 reads (28%) | called by muse, mutect2, varscan2
- ABCA7 | c.4875G>C p.L1625= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs754027385; called by muse, mutect2, varscan2
- ADAMTS5 | c.984G>A p.L328= | Silent (SNP) | VAF 51/345 reads (15%) | catalogued as rs760808495; called by muse, mutect2, varscan2
- AKR7L | c.114C>T p.R38= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs1407149194; called by muse, mutect2, varscan2
- BTBD1 | c.966A>G p.R322= | Silent (SNP) | VAF 56/355 reads (16%) | called by muse, mutect2, varscan2
- FOXD3 | c.1179C>T p.G393= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as rs929422083; called by muse, mutect2, varscan2
- IGHV3-33 | c.69G>C p.L23= | Silent (SNP) | VAF 29/118 reads (25%) | called by muse, varscan2
- LOXHD1 | c.57C>T p.Y19= | Silent (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- LTB4R2 | c.283C>T p.L95= (on ENST00000528054; = p.L64= on NM_019839.5) | Silent (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- METTL11B | c.375C>T p.S125= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1456074952, COSV63030163; called by mutect2, varscan2
- MSH3 | c.984G>T p.R328= | Silent (SNP) | VAF 49/797 reads (6%) | called by muse, mutect2
- PIWIL4 | c.2247C>T p.N749= | Silent (SNP) | VAF 49/232 reads (21%) | catalogued as rs756931190; called by muse, mutect2, varscan2
- RIPK4 | c.177C>T p.D59= | Silent (SNP) | VAF 35/246 reads (14%) | called by muse, mutect2, varscan2
- TNS3 | c.2787C>A p.T929= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.408C>T p.R136= | Silent (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- AC020765.6 | c.-42G>A | 5'UTR (SNP) | VAF 22/47 reads (47%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23980142 T>C | 5'Flank (SNP) | VAF 31/143 reads (22%) | called by muse, mutect2, varscan2
- ANKH | c.*4608C>T | 3'UTR (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- ARRB1 | c.21-16545C>T | Intron (SNP) | VAF 47/452 reads (10%) | called by muse, mutect2, varscan2
- ATP6V0E2 | chr7:149873497 G>T | 5'Flank (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.950G>T | RNA (SNP) | VAF 152/846 reads (18%) | called by muse, mutect2
- BARD1 | c.215+31C>T | Intron (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2
- C9orf57 | c.*2T>C | 3'UTR (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- CCN2 | c.*785T>C | 3'UTR (SNP) | VAF 33/124 reads (27%) | catalogued as rs867008423; called by muse, mutect2, varscan2
- CDH6 | c.*637A>G | 3'UTR (SNP) | VAF 44/193 reads (23%) | called by muse, mutect2, varscan2
- CEP170 | c.1843+246A>G | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs199610432; called by muse, mutect2
- DEFB134 | chr8:11993557 A>T | 3'Flank (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- DLX6 | c.-246C>G | 5'UTR (SNP) | VAF 22/87 reads (25%) | called by muse, varscan2
- EYS | c.862+45A>T | Intron (SNP) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- FAM171A1 | c.*814G>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- FAM217B | c.*1232T>A | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- FASTKD2 | c.2013+14G>A | Intron (SNP) | VAF 57/176 reads (32%) | catalogued as COSV52700286; called by muse, mutect2, varscan2
- FASTKD2 | c.2013+15C>T | Intron (SNP) | VAF 56/175 reads (32%) | called by muse, mutect2, varscan2
- FLCN | c.-24-703_-24-693del | Intron (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- FOXK1 | c.*6792G>A | 3'UTR (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- FOXK2 | c.*322G>T | 3'UTR (SNP) | VAF 52/130 reads (40%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+4543C>T | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137035862 G>A | 5'Flank (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
- GBX2 | c.-401C>T | 5'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- GOLGA7B | c.*1762T>C | 3'UTR (SNP) | VAF 38/91 reads (42%) | called by muse, mutect2, varscan2
- GRIN1 | c.2589+66C>T | Intron (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- IBA57 | c.*493G>A | 3'UTR (SNP) | VAF 60/148 reads (41%) | catalogued as rs941484757; called by muse, mutect2, varscan2
- INTS11 | c.429+196C>T | Intron (SNP) | VAF 75/196 reads (38%) | catalogued as rs755105272; called by muse, mutect2, varscan2
- INTS4P2 | n.1230G>C | RNA (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- ITGA9 | c.2154+54C>A | Intron (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- KIF1A | c.*3162C>A | 3'UTR (SNP) | VAF 61/199 reads (31%) | called by muse, mutect2, varscan2
- KIFC3 | c.172+79C>T | Intron (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- KLF12 | c.*1496G>A | 3'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- KLRF1 | c.-50T>C | 5'UTR (SNP) | VAF 51/133 reads (38%) | called by muse, mutect2, varscan2
- KMT5B | c.*1329A>T | 3'UTR (SNP) | VAF 48/94 reads (51%) | called by muse, mutect2, varscan2
- LINC02692 | n.828G>T | RNA (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- LTBP1 | c.-179T>G | 5'UTR (SNP) | VAF 93/168 reads (55%) | called by muse, mutect2, varscan2
- LYSMD2 | c.*131C>T | 3'UTR (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2, varscan2
- MAGI2 | c.-3G>A | 5'UTR (SNP) | VAF 119/209 reads (57%) | catalogued as rs759941427; called by muse, mutect2, varscan2
- MMS22L | c.607-321G>A | Intron (SNP) | VAF 19/57 reads (33%) | catalogued as rs536379694; called by muse, mutect2, varscan2
- MRGPRX10P | n.245C>T | RNA (SNP) | VAF 27/118 reads (23%) | catalogued as rs1007764171; called by muse, mutect2, varscan2
- MRGPRX10P | n.75A>G | RNA (SNP) | VAF 44/189 reads (23%) | called by muse, mutect2, varscan2
- MYRIP | c.-21C>T | 5'UTR (SNP) | VAF 112/365 reads (31%) | called by muse, mutect2, varscan2
- NR2F1 | c.-678C>T | 5'UTR (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- NUDT4 | c.*8387T>A | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- NUP160 | c.*981T>G | 3'UTR (SNP) | VAF 22/88 reads (25%) | called by muse, varscan2
- NUP160 | c.*922T>G | 3'UTR (SNP) | VAF 26/107 reads (24%) | called by muse, varscan2
- OCM2 | c.-60T>A | 5'UTR (SNP) | VAF 138/447 reads (31%) | called by muse, mutect2, varscan2
- OR5M4P | n.433T>A | RNA (SNP) | VAF 80/121 reads (66%) | called by muse, mutect2, varscan2
- PDE10A | c.2268-150C>G | Intron (SNP) | VAF 21/33 reads (64%) | called by muse, varscan2
- PDE8A | c.*1185A>T | 3'UTR (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- PDGFRB | c.*676C>T | 3'UTR (SNP) | VAF 34/97 reads (35%) | called by muse, mutect2, varscan2
- PDLIM3 | c.94-67C>T | Intron (SNP) | VAF 52/95 reads (55%) | called by muse, mutect2, varscan2
- PTGER2 | c.*389C>A | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- RASA3 | c.*352A>G | 3'UTR (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- RINL | c.1342+83G>C | Intron (SNP) | VAF 32/164 reads (20%) | called by mutect2, varscan2
- RND1 | c.*586T>G | 3'UTR (SNP) | VAF 51/130 reads (39%) | called by muse, mutect2, varscan2
- RNF123 | c.2674+387T>C | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- RRP15 | c.*5095C>T | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- SEC16B | c.999-84T>C | Intron (SNP) | VAF 21/115 reads (18%) | called by muse, mutect2, varscan2
- SH2B3 | c.*635C>T | 3'UTR (SNP) | VAF 61/152 reads (40%) | called by muse, mutect2, varscan2
- SHOX2 | c.347-1254C>T | Intron (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SLC38A10 | c.-243G>A | 5'UTR (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- SNX13 | c.441-6613_441-6612del | Intron (DEL) | VAF 39/183 reads (21%) | catalogued as rs1376814459; called by mutect2, pindel, varscan2
- SP8 | c.-233A>G | 5'UTR (SNP) | VAF 129/487 reads (26%) | called by muse, mutect2, varscan2
- SSBP3 | c.*410C>T | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- ST3GAL2 | c.*507A>G | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- TMEM170A | c.*4274A>G | 3'UTR (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- TRA2B | c.37-70C>G | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- TSPEAR | c.1566+2127G>A | Intron (SNP) | VAF 58/320 reads (18%) | catalogued as rs906476505; called by muse, mutect2, varscan2
- TTLL5 | c.740+1680G>A | Intron (SNP) | VAF 56/108 reads (52%) | called by muse, mutect2, varscan2
- WNT2B | c.*497C>T | 3'UTR (SNP) | VAF 32/88 reads (36%) | catalogued as rs918441591; called by muse, mutect2, varscan2
- ZIC4 | c.*-147G>T | Intron (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2
